Somatic mutation profile of tumor specimen C3L-00923-03 (aliquot CPT0063430009) from CPTAC case C3L-00923, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.2 years (25,994 days).
Specimen C3L-00923-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd3b7f2c-d9c6-423f-9699-023ae3bab8cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00923-31 (Blood Derived Normal), aliquot CPT0065260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1820e807-b338-48f5-ae82-bce4c34a0421

The open-access MAF lists 187 somatic variants for this specimen: 114 protein-altering or splice-affecting, 55 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 55, Frame Shift Del 7, Intron 6, Nonsense Mutation 5, 5'UTR 4, 3'UTR 4, Frame Shift Ins 3, RNA 3, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 17/176 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.2656G>A p.G886S | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV52033055; called by muse, mutect2
- AK9 | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as COSV100393750; called by muse, mutect2
- ATG4B | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1422726715; called by muse, mutect2
- ATP7A | c.2157G>T p.L719F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as rs1557234540; called by muse, mutect2
- B4GALT7 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.247); catalogued as rs1433365660; called by muse, mutect2
- BCORL1 | c.5018G>C p.G1673A | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.044); catalogued as COSV54403242; called by muse, mutect2
- C3 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 58/731 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs771248231; called by muse, mutect2
- CNST | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1200962952; called by muse, mutect2
- COLEC12 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV68373250; called by muse, mutect2, varscan2
- CPN2 | c.146del p.P49Hfs*27 | Frame Shift Del (DEL) | VAF 35/221 reads (16%) | catalogued as COSV60469593; called by mutect2, pindel, varscan2
- DLD | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756535329; called by muse, mutect2
- DNAH7 | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.598); catalogued as rs928057767; called by muse, mutect2, varscan2
- FAM83B | c.1685G>C p.G562A | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV60922037; called by muse, mutect2
- FLG | c.3126C>G p.D1042E | Missense Mutation (SNP) | VAF 52/836 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs759531140; called by muse, mutect2
- FRMPD2 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 33/378 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as rs1350311842; called by muse, mutect2
- GSDME | c.1220G>A p.C407Y | Missense Mutation (SNP) | VAF 36/806 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243479185; called by muse, mutect2
- HOXC13 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 48/813 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1429467402, COSV54497895; called by muse, mutect2
- LILRA2 | c.1146G>A p.M382I | Missense Mutation (SNP) | VAF 42/647 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs373786652; called by muse, mutect2
- MID1 | c.947C>A p.A316E | Missense Mutation (SNP) | VAF 45/503 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs398123344, COSV58198947; ClinVar: uncertain significance; called by muse, mutect2
- MSH3 | c.1895A>C p.K632T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54165438; called by muse, mutect2
- NLRP12 | c.3007C>A p.L1003I | Missense Mutation (SNP) | VAF 50/892 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367741104, COSV100145029; called by muse, mutect2
- NTSR1 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs556913630; called by muse, mutect2
- OBSL1 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54729722; called by muse, mutect2, varscan2
- OR8K1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1187771580; called by muse, mutect2
- PCDH11X | c.1553G>T p.R518L | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); catalogued as COSV53497403; called by muse, mutect2
- PGM2L1 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99994772; called by muse, mutect2, varscan2
- PLXNA1 | c.2504G>T p.R835L | Missense Mutation (SNP) | VAF 54/522 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.33); catalogued as COSV52530300; called by muse, mutect2
- PLXNA4 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV58113377, COSV58165790; called by muse, mutect2, varscan2
- PNLIPRP1 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62611716; called by muse, mutect2
- PODN | c.1496G>A p.R499Q (on ENST00000395871; = p.R451Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs372626429; called by muse, mutect2
- RASIP1 | c.949C>A p.R317S | Missense Mutation (SNP) | VAF 50/439 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs767527552; called by muse, mutect2, varscan2
- SCIN | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51689037; called by muse, mutect2
- SLC16A2 | c.1246G>A p.V416I | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as CM151145, COSV52085158; called by muse, mutect2
- STKLD1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs1272016975; called by muse, mutect2
- TEX13C | c.1049del p.P350Qfs*14 | Frame Shift Del (DEL) | VAF 57/527 reads (11%) | catalogued as COSV58901583; called by mutect2, pindel
- TMEM177 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 20/231 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs747648660; called by muse, mutect2
- TP53 | c.145del p.D49Ifs*74 | Frame Shift Del (DEL) | VAF 32/338 reads (9%) | catalogued as COSV52732514, COSV52864415, COSV52865140; called by mutect2, pindel
- UGT2B4 | c.1140C>G p.I380M | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs772777922, COSV59319932; called by muse, mutect2, varscan2
- ZFP41 | c.350G>A p.C117Y | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772618145, COSV58087133; called by muse, mutect2
- ZFP42 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 28/431 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58818275; called by muse, mutect2
- ZNF728 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV74099080; called by muse, mutect2
- AC098582.1 | c.1253A>T p.N418I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by mutect2, varscan2
- AC244197.3 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ACAN | c.6319C>A p.P2107T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.912); called by muse, mutect2
- ACAP3 | c.1628G>T p.S543I | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- AK5 | c.1277G>T p.R426I (on ENST00000354567 / NM_174858.3; = p.R400I on NM_012093.4) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ARHGEF6 | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- BLM | c.2696G>T p.R899L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2
- C6 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- CBWD6 | c.1055A>C p.E352A | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CDH9 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYLC1 | c.1469T>A p.L490* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- CYP2A13 | c.111del p.T38Pfs*12 | Frame Shift Del (DEL) | VAF 22/252 reads (9%) | called by mutect2, pindel
- DELEC1 | n.604A>G | Splice Region (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- DNAAF3 | c.1023G>C p.E341D (on ENST00000524407 / NM_001256715.2; = p.E388D on NM_178837.4) | Missense Mutation (SNP) | VAF 66/645 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.068); called by muse, mutect2
- DNAH8 | c.5648G>T p.R1883M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EIF5B | c.2144_2145insC p.R715Sfs*7 | Frame Shift Ins (INS) | VAF 3/37 reads (8%) | called by mutect2, pindel
- ERCC2 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2
- FIBCD1 | c.779T>A p.V260D | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- GAB3 | c.313A>T p.M105L | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GBX1 | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 33/481 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2
- GOLGA6L2 | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.077); called by muse, mutect2
- GPLD1 | c.2158G>T p.G720C | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HEATR5A | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- HECW1 | c.3736G>T p.G1246C | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.12523G>A p.E4175K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- HOXD13 | c.368del p.P123Qfs*143 | Frame Shift Del (DEL) | VAF 50/563 reads (9%) | called by mutect2, pindel
- HS1BP3 | c.836A>G p.D279G | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- IL10RB | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRFN5 | c.1124T>G p.I375S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2
- MAP3K13 | c.2168G>T p.C723F | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); called by muse, mutect2
- MNX1 | c.678G>T p.M226I | Missense Mutation (SNP) | VAF 23/289 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2
- MROH2B | c.2540G>T p.S847I | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- MTDH | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 87/774 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MTMR9 | c.1630G>T p.G544W | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, mutect2
- MTUS2 | c.1907A>G p.K636R | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.799); called by muse, mutect2
- NFATC4 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2
- NLGN4X | c.2072T>A p.L691* | Nonsense Mutation (SNP) | VAF 54/710 reads (8%) | called by muse, mutect2
- OBSCN | c.11891G>C p.G3964A | Missense Mutation (SNP) | VAF 56/720 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- OR10R2 | c.191C>G p.T64S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PCIF1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PFKFB3 | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 22/167 reads (13%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHKA2 | c.2579G>T p.R860L | Missense Mutation (SNP) | VAF 62/712 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLEKHG1 | c.462A>T p.E154D | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- PLEKHG4 | c.1850dup p.S618Lfs*27 | Frame Shift Ins (INS) | VAF 34/290 reads (12%) | called by mutect2, pindel
- PRAMEF20 | c.1272C>G p.I424M | Missense Mutation (SNP) | VAF 80/1164 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- PRUNE2 | c.3076G>C p.G1026R | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2
- PTCHD4 | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- RBM20 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 58/812 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); called by muse, mutect2
- RIMS2 | c.1526A>G p.Q509R (on ENST00000666250 / NM_001348490.2; = p.Q317R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2
- RPGR | c.2520+5G>T | Splice Region (SNP) | VAF 21/408 reads (5%) | called by muse, mutect2
- RUSC1 | c.2563C>T p.H855Y (on ENST00000368352 / NM_001105203.2; = p.H386Y on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- RYR2 | c.14408A>T p.D4803V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCML2 | c.598del p.D200Mfs*33 | Frame Shift Del (DEL) | VAF 14/158 reads (9%) | called by mutect2, pindel
- SDK1 | c.2264G>A p.S755N | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEMA3G | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2
- SEPTIN2 | c.385T>A p.Y129N | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC10A3 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- SOWAHD | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPEG | c.9002C>A p.A3001D | Missense Mutation (SNP) | VAF 33/437 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- SPTBN4 | c.5208del p.S1737Afs*51 | Frame Shift Del (DEL) | VAF 26/272 reads (10%) | called by mutect2, pindel
- TBRG4 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- TET3 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TEX13C | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.38); called by muse, mutect2
- TMEM132D | c.2768dup p.L923Ffs*41 | Frame Shift Ins (INS) | VAF 30/366 reads (8%) | called by mutect2, pindel
- TNNT3 | c.373G>T p.E125* (on ENST00000397301 / NM_001367846.1; = p.E114* on NM_006757.4) | Nonsense Mutation (SNP) | VAF 96/1042 reads (9%) | called by muse, mutect2
- TTN | c.85012A>T p.T28338S (on ENST00000591111; = p.T20914S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/105 reads (8%) | PolyPhen benign (0.173); called by muse, mutect2
- TTN | c.36607G>A p.D12203N (on ENST00000591111; = p.D4779N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | PolyPhen possibly damaging (0.796); called by muse, mutect2
- TTN | c.36520G>A p.D12174N (on ENST00000591111; = p.D4750N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/148 reads (9%) | PolyPhen benign (0.038); called by muse, mutect2
- VIRMA | c.640A>G p.R214G | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2
- ZNF208 | c.2892G>T p.K964N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF233 | c.1760C>A p.T587K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF560 | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASPM | c.3441G>C p.L1147= | Silent (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
- ATRX | c.1989C>A p.P663= | Silent (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- BLVRB | c.525C>T p.V175= | Silent (SNP) | VAF 33/257 reads (13%) | catalogued as rs527721383, COSV54569135; called by muse, mutect2, varscan2
- C5 | c.2457G>A p.V819= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- CARD6 | c.498G>A p.E166= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- CDC14A | c.762A>T p.T254= | Silent (SNP) | VAF 38/612 reads (6%) | called by muse, mutect2
- CHTF18 | c.2229C>A p.G743= | Silent (SNP) | VAF 16/329 reads (5%) | called by muse, mutect2
- CNST | c.153G>T p.L51= | Silent (SNP) | VAF 23/340 reads (7%) | called by muse, mutect2
- CRX | c.121C>A p.R41= | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as CM970397, COSV55758646; called by muse, mutect2
- DCC | c.1290G>A p.S430= | Silent (SNP) | VAF 36/638 reads (6%) | catalogued as rs773303536, COSV59113023; called by muse, mutect2
- DCST1 | c.1722C>T p.L574= | Silent (SNP) | VAF 52/368 reads (14%) | catalogued as COSV99664750; called by muse, varscan2
- ENTPD6 | c.1194G>A p.E398= | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.9933T>A p.V3311= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- GDF2 | c.993C>A p.S331= | Silent (SNP) | VAF 33/422 reads (8%) | called by muse, mutect2
- GGT1 | c.792G>T p.P264= | Silent (SNP) | VAF 28/556 reads (5%) | called by muse, mutect2
- GLT6D1 | c.681T>C p.Y227= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs747558905; called by muse, mutect2, varscan2
- HEATR1 | c.1356A>T p.A452= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- HUWE1 | c.7659G>A p.L2553= | Silent (SNP) | VAF 32/561 reads (6%) | called by muse, mutect2
- IER5 | c.774G>T p.A258= | Silent (SNP) | VAF 49/630 reads (8%) | called by muse, mutect2
- IGSF10 | c.2841A>G p.S947= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2, varscan2
- KLHL34 | c.606T>A p.A202= | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- LAMP2 | c.954C>A p.L318= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- MAGEA11 | c.1131T>A p.T377= | Silent (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- MAGED1 | c.1539T>C p.I513= | Silent (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- MED15 | c.2082C>T p.D694= (on ENST00000263205 / NM_001003891.3; = p.D654= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/256 reads (6%) | called by muse, mutect2
- MYOCD | c.1683G>A p.K561= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- NCAN | c.3387G>A p.P1129= | Silent (SNP) | VAF 51/534 reads (10%) | catalogued as rs771758417, COSV53048906; called by muse, mutect2
- OR4D10 | c.498C>A p.L166= | Silent (SNP) | VAF 15/254 reads (6%) | catalogued as COSV73260220; called by muse, mutect2
- OR5AU1 | c.741C>A p.A247= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV58615543; called by muse, mutect2
- OTULINL | c.51C>G p.G17= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as rs1421571480; called by muse, mutect2
- PCDH11X | c.1764A>G p.T588= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs758458874; called by muse, mutect2
- PCDHGA11 | c.1737G>A p.A579= | Silent (SNP) | VAF 47/475 reads (10%) | catalogued as COSV53930374; called by muse, mutect2, varscan2
- PDYN | c.165C>T p.P55= | Silent (SNP) | VAF 19/320 reads (6%) | catalogued as rs1299464285; called by muse, mutect2
- PGM1 | c.801C>G p.T267= | Silent (SNP) | VAF 32/370 reads (9%) | catalogued as COSV64301197; called by muse, mutect2
- PI3 | c.312C>T p.C104= | Silent (SNP) | VAF 26/355 reads (7%) | catalogued as rs911982108; called by muse, mutect2
- PIK3C2B | c.3597C>T p.D1199= | Silent (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
- PLG | c.855G>T p.G285= | Silent (SNP) | VAF 43/622 reads (7%) | catalogued as rs202061577, COSV51987197; called by muse, mutect2
- PRDX6 | c.192G>A p.R64= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2, varscan2
- PTPRE | c.177C>T p.L59= | Silent (SNP) | VAF 34/348 reads (10%) | catalogued as COSV99616810; called by muse, mutect2, varscan2
- RBL2 | c.1953T>G p.A651= | Silent (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2
- RBMX2 | c.207G>T p.R69= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- RPS4X | c.144G>A p.L48= | Silent (SNP) | VAF 17/206 reads (8%) | catalogued as rs773369444, COSV60181791; called by muse, mutect2
- SBK1 | c.756G>C p.P252= | Silent (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- SLC13A4 | c.657C>A p.T219= | Silent (SNP) | VAF 11/222 reads (5%) | called by muse, mutect2
- SLC6A5 | c.2268G>A p.P756= | Silent (SNP) | VAF 36/675 reads (5%) | catalogued as rs373204248; ClinVar: likely benign; called by muse, mutect2
- SLC8B1 | c.78G>T p.G26= | Silent (SNP) | VAF 23/321 reads (7%) | called by muse, mutect2
- SLFN11 | c.2145C>T p.L715= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs767890093; called by muse, mutect2, varscan2
- SMARCAL1 | c.2511A>C p.T837= | Silent (SNP) | VAF 68/898 reads (8%) | called by muse, mutect2
- SOWAHD | c.81G>T p.P27= | Silent (SNP) | VAF 25/248 reads (10%) | called by muse, mutect2, varscan2
- SPDEF | c.39C>T p.P13= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs1486766193; called by muse, mutect2, varscan2
- SYNE1 | c.1422G>T p.G474= (on ENST00000367255 / NM_182961.4; = p.G481= on NM_033071.3) | Silent (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- TBX6 | c.576C>T p.F192= | Silent (SNP) | VAF 20/181 reads (11%) | called by muse, mutect2, varscan2
- TRRAP | c.5790G>T p.A1930= (on ENST00000359863 / NM_001244580.1; = p.A1912= on NM_003496.3) | Silent (SNP) | VAF 39/409 reads (10%) | called by muse, mutect2
- USH2A | c.7662G>A p.Q2554= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- ZFHX4 | c.2919G>T p.L973= | Silent (SNP) | VAF 19/273 reads (7%) | catalogued as COSV50481680, COSV51498482; called by muse, mutect2
- AC073621.1 | n.603G>T | RNA (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- ADGRE4P | n.1107G>A | RNA (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- APOO | c.*30-3235G>T | Intron (SNP) | VAF 12/99 reads (12%) | called by mutect2, varscan2
- ASB10 | chr7:151187486 C>A | 5'Flank (SNP) | VAF 31/392 reads (8%) | called by muse, mutect2
- BCL2L11 | c.499-2714A>G | Intron (SNP) | VAF 23/290 reads (8%) | called by muse, mutect2
- CFL2 | c.*194A>T | 3'UTR (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- DUSP23 | c.*2G>T | 3'UTR (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- GVINP1 | n.2603A>C | RNA (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- KCNAB1 | c.276-129505G>A | Intron (SNP) | VAF 36/450 reads (8%) | called by muse, mutect2
- LAMP2 | c.-17G>T | 5'UTR (SNP) | VAF 38/454 reads (8%) | called by muse, mutect2
- LRRC9 | c.-4G>T | 5'UTR (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-16437T>C | Intron (SNP) | VAF 6/80 reads (8%) | catalogued as rs1357608090; called by muse, mutect2
- PUDP | c.511-7283G>T | Intron (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- RIPK4 | c.-16T>A | 5'UTR (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- RTL8B | c.*233G>A | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- RTN1 | c.1766-2676G>T | Intron (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- THAP3 | c.-14A>T | 5'UTR (SNP) | VAF 41/602 reads (7%) | called by muse, mutect2
- UMPS | c.*2080C>T | 3'UTR (SNP) | VAF 23/337 reads (7%) | catalogued as rs758048526; called by muse, mutect2
